Somatic mutation profile of tumor specimen TCGA-ED-A7PZ-01A (aliquot TCGA-ED-A7PZ-01A-11D-A33Q-10) from TCGA case TCGA-ED-A7PZ, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 61.9 years (22,601 days).
Specimen TCGA-ED-A7PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dc6dafd7-b608-43a3-abe9-c56d6b0fb305.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ED-A7PZ-10A (Blood Derived Normal), aliquot TCGA-ED-A7PZ-10A-01D-A33Q-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/098a2093-073c-421e-a145-c4e1d0ad5aba

The open-access MAF lists 280 somatic variants for this specimen: 227 protein-altering or splice-affecting, 51 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 204, Silent 51, Splice Site 7, Nonsense Mutation 6, Frame Shift Del 3, In Frame Del 3, Frame Shift Ins 2, Intron 1, Translation Start Site 1, RNA 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>G p.D32G | Missense Mutation (SNP) | VAF 99/107 reads (93%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.904A>T p.T302S | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.431); catalogued as COSV70026628; called by muse, mutect2, varscan2
- ABCA4 | c.769-2A>T p.X257_splice | Splice Site (SNP) | VAF 6/51 reads (12%) | catalogued as CS1210012, COSV64671820; called by muse, mutect2, varscan2
- ABCC4 | c.2174A>T p.Q725L | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.169); catalogued as COSV65310560; called by muse, mutect2, varscan2
- ACAP1 | c.1406T>A p.L469Q | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as rs1477902401, COSV50134387; called by muse, mutect2, varscan2
- ADAM23 | c.1366T>A p.W456R | Missense Mutation (SNP) | VAF 24/49 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV52210113; called by muse, mutect2, varscan2
- ADAMTS19 | c.1783A>T p.T595S | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0.031); catalogued as COSV50735427; called by muse, mutect2, varscan2
- ADGRG5 | c.1364A>G p.D455G | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61082781; called by muse, mutect2
- AKNA | c.866G>A p.C289Y | Missense Mutation (SNP) | VAF 25/29 reads (86%) | SIFT tolerated (0.39); PolyPhen benign (0.059); catalogued as COSV56311533; called by muse, mutect2, varscan2
- AOC2 | c.1815C>G p.S605R | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53825109; called by muse, mutect2, varscan2
- ARHGEF26 | c.1114G>C p.D372H | Missense Mutation (SNP) | VAF 26/43 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV62844654; called by muse, mutect2, varscan2
- ASTN1 | c.2186T>C p.F729S | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV56063977; called by muse, mutect2, varscan2
- ATP8B3 | c.1894C>A p.L632M | Missense Mutation (SNP) | VAF 35/72 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59541014; called by muse, mutect2, varscan2
- ATP9A | c.798A>T p.S266= | Splice Region (SNP) | VAF 62/98 reads (63%) | catalogued as COSV58764262; called by muse, mutect2, varscan2
- AVL9 | c.1195C>A p.P399T | Missense Mutation (SNP) | VAF 32/123 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59464620; called by muse, mutect2, varscan2
- B4GALT6 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.078); catalogued as COSV52702889; called by muse, mutect2, varscan2
- BCLAF1 | c.1484A>T p.Q495L | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.887); catalogued as COSV62141023; called by muse, mutect2, varscan2
- BICDL2 | c.92T>A p.L31Q | Missense Mutation (SNP) | VAF 37/61 reads (61%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); catalogued as COSV66369743; called by muse, mutect2, varscan2
- BMPR2 | c.530-2A>T p.X177_splice | Splice Site (SNP) | VAF 18/57 reads (32%) | catalogued as COSV65808064; called by muse, mutect2, varscan2
- C12orf56 | c.470T>A p.L157Q | Missense Mutation (SNP) | VAF 56/67 reads (84%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as COSV61485795; called by muse, mutect2, varscan2
- CACNA1C | c.3419T>A p.V1140E | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59703181; called by muse, mutect2, varscan2
- CAPN11 | c.1913T>A p.L638Q | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67236671; called by muse, mutect2, varscan2
- CD44 | c.1811-2A>T p.X604_splice | Splice Site (SNP) | VAF 34/53 reads (64%) | catalogued as COSV53528478; called by muse, mutect2, varscan2
- CDH15 | c.1049C>A p.A350E | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0.347); catalogued as COSV57022553; called by muse, mutect2, varscan2
- CEACAM7 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 82/124 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV50072577; called by muse, mutect2, varscan2
- CEP131 | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV53951289; called by muse, mutect2, varscan2
- CHD9 | c.6831A>C p.K2277N | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54608544; called by muse, mutect2, varscan2
- CLEC2B | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 56/73 reads (77%) | SIFT deleterious (0); PolyPhen benign (0.115); catalogued as COSV57308837; called by muse, mutect2, varscan2
- CLP1 | c.518A>T p.D173V | Missense Mutation (SNP) | VAF 29/54 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV57054044; called by muse, mutect2, varscan2
- CLRN3 | c.400G>T p.G134W | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64098308; called by muse, mutect2, varscan2
- CNPY1 | c.92A>T p.E31V | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as COSV58786864; called by muse, mutect2, varscan2
- CNR1 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 86/97 reads (89%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.012); catalogued as rs1402515300, COSV62986697; called by muse, mutect2, varscan2
- CNRIP1 | c.309A>T p.Q103H | Missense Mutation (SNP) | VAF 62/107 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV55147894; called by muse, mutect2, varscan2
- COL16A1 | c.1258-1G>T p.X420_splice | Splice Site (SNP) | VAF 78/177 reads (44%) | catalogued as COSV54702042; called by muse, mutect2, varscan2
- CPA4 | c.1078T>A p.Y360N | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55982598; called by muse, mutect2, varscan2
- CRTC2 | c.1124C>A p.S375Y | Missense Mutation (SNP) | VAF 34/52 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57841457, COSV57842696; called by muse, mutect2, varscan2
- CSMD3 | c.9448C>A p.P3150T (on ENST00000297405 / NM_001363185.1; = p.P2981T on NM_052900.3) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.57); PolyPhen benign (0.005); catalogued as COSV52126774; called by muse, mutect2, varscan2
- CSRNP3 | c.1304T>A p.L435Q | Missense Mutation (SNP) | VAF 31/55 reads (56%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.478); catalogued as COSV58776139; called by muse, mutect2, varscan2
- CTCF | c.1620G>A p.M540I | Missense Mutation (SNP) | VAF 105/166 reads (63%) | SIFT tolerated (0.27); PolyPhen benign (0.063); catalogued as COSV50462970; called by muse, mutect2, varscan2
- CXXC5 | c.586G>A p.V196M | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.823); catalogued as COSV56793274; called by muse, mutect2, varscan2
- DACT1 | c.1256G>T p.W419L | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.086); catalogued as COSV60019845; called by muse, mutect2, varscan2
- DCST1 | c.1896C>A p.H632Q | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV55057305; called by muse, mutect2, varscan2
- DDX43 | c.1197C>A p.D399E | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64812367; called by muse, mutect2, varscan2
- DENND3 | c.269A>G p.Y90C | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV52801331; called by muse, mutect2, varscan2
- DISC1 | c.2140C>A p.L714M | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV64092776; called by muse, mutect2, varscan2
- DMD | c.4181C>A p.A1394E | Missense Mutation (SNP) | VAF 56/56 reads (100%) | SIFT deleterious (0); PolyPhen benign (0.087); catalogued as COSV63740909; called by muse, mutect2, varscan2
- DNAH7 | c.4430T>A p.L1477Q | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56755864; called by muse, mutect2, varscan2
- DOCK10 | c.2791G>C p.D931H | Missense Mutation (SNP) | VAF 19/53 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV51358238; called by muse, mutect2, varscan2
- DRC7 | c.11T>A p.L4Q | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV61053564; called by muse, mutect2, varscan2
- DRD2 | c.1180A>G p.I394V | Missense Mutation (SNP) | VAF 61/98 reads (62%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.557); catalogued as rs1171568451, COSV60755448; called by muse, mutect2, varscan2
- EPC1 | c.2236A>T p.T746S | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT tolerated (0.61); PolyPhen benign (0.015); catalogued as COSV53923790; called by muse, mutect2, varscan2
- EPHA10 | c.41T>A p.L14H | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.487); catalogued as COSV60402510; called by muse, mutect2, varscan2
- EPSTI1 | c.948G>T p.W316C (on ENST00000398762 / NM_001330543.2; = p.W305C on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100553267; called by muse, mutect2, varscan2
- EPSTI1 | c.947G>T p.W316L (on ENST00000398762 / NM_001330543.2; = p.W305L on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100553269; called by muse, mutect2, varscan2
- ERBIN | c.1104A>C p.Q368H | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52312460; called by muse, mutect2, varscan2
- FAT3 | c.7982T>C p.V2661A | Missense Mutation (SNP) | VAF 49/80 reads (61%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.84); catalogued as COSV53087350; called by muse, mutect2, varscan2
- FCHO1 | c.1138C>A p.L380I | Missense Mutation (SNP) | VAF 31/33 reads (94%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.991); catalogued as COSV53181327; called by muse, mutect2, varscan2
- FER1L6 | c.5480T>A p.I1827N | Missense Mutation (SNP) | VAF 62/116 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs375758950, COSV67548703; called by muse, mutect2, varscan2
- FGFR4 | c.1130C>T p.S377F | Missense Mutation (SNP) | VAF 23/78 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV52801673; called by muse, mutect2, varscan2
- FLYWCH1 | c.446A>G p.Q149R (on ENST00000253928 / NM_001308068.2; = p.Q148R on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.018); catalogued as COSV54144156; called by muse, varscan2
- FRMPD2 | c.2372A>T p.N791I | Missense Mutation (SNP) | VAF 27/74 reads (36%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as COSV59716118; called by muse, mutect2, varscan2
- GABBR2 | c.2120C>T p.A707V | Missense Mutation (SNP) | VAF 66/73 reads (90%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.989); catalogued as COSV52296198; called by muse, mutect2, varscan2
- GJA5 | c.869A>G p.Q290R | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV54783270; called by muse, mutect2, varscan2
- GLI3 | c.2366T>A p.M789K | Missense Mutation (SNP) | VAF 64/138 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.017); catalogued as COSV67886221; called by muse, mutect2, varscan2
- GRIA1 | c.685A>T p.I229F | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); catalogued as COSV53593265; called by muse, mutect2, varscan2
- GRIN3B | c.1895T>A p.V632E | Missense Mutation (SNP) | VAF 67/92 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV52258997; called by muse, mutect2, varscan2
- GSTA4 | c.377A>T p.Q126L | Missense Mutation (SNP) | VAF 61/147 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV63955306; called by muse, mutect2, varscan2
- GTF2IRD2B | c.241G>T p.V81F | Missense Mutation (SNP) | VAF 244/854 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); catalogued as COSV100441328; called by muse, mutect2, varscan2
- GZF1 | c.1904C>T p.S635L | Missense Mutation (SNP) | VAF 13/118 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.125); catalogued as rs750525985, COSV57635270; called by muse, mutect2
- HBE1 | c.70G>T p.A24S | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV53079683; called by muse, mutect2, varscan2
- HDAC7 | c.391A>C p.S131R (on ENST00000427332; = p.S170R on NM_015401.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/68 reads (75%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as COSV50322345, COSV50324761; called by muse, mutect2, varscan2
- HECW1 | c.2192C>A p.T731K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as COSV101223463, COSV67824903; called by muse, mutect2, varscan2
- HERC2 | c.6178G>C p.A2060P | Missense Mutation (SNP) | VAF 59/93 reads (63%) | SIFT tolerated (0.19); PolyPhen benign (0.024); catalogued as rs558450056, COSV55309864, COSV55312927; called by muse, mutect2, varscan2
- HIPK2 | c.160A>T p.S54C | Missense Mutation (SNP) | VAF 61/113 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.293); catalogued as rs907544638, COSV100702670; called by muse, mutect2, varscan2
- HIPK2 | c.159G>T p.Q53H | Missense Mutation (SNP) | VAF 61/115 reads (53%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV100702673; called by muse, mutect2, varscan2
- HIVEP1 | c.4066G>T p.V1356F | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV65099553; called by muse, mutect2, varscan2
- HYDIN | c.14566A>T p.N4856Y | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66637872; called by muse, mutect2, varscan2
- IGDCC4 | c.997G>T p.A333S | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs767900209, COSV61535829; called by muse, mutect2, varscan2
- IGF2BP3 | c.586T>A p.L196M | Missense Mutation (SNP) | VAF 33/67 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as COSV51681477; called by muse, mutect2, varscan2
- IGKV5-2 | c.260A>T p.Y87F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs762248458; called by muse, mutect2, varscan2
- IL13RA2 | c.266T>A p.L89Q | Missense Mutation (SNP) | VAF 38/41 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV54564326; called by muse, mutect2, varscan2
- IL17RD | c.1103A>C p.Q368P | Missense Mutation (SNP) | VAF 69/78 reads (88%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as COSV56336007; called by muse, mutect2, varscan2
- IMPA2 | c.628G>T p.A210S | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.014); catalogued as COSV52318968; called by muse, mutect2, varscan2
- INHA | c.617C>A p.S206* | Nonsense Mutation (SNP) | VAF 14/37 reads (38%) | catalogued as COSV54714799, COSV99217513; called by muse, mutect2, varscan2
- INTU | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT tolerated (0.07); PolyPhen benign (0.219); catalogued as COSV58870086; called by muse, mutect2, varscan2
- IRX4 | c.142T>A p.Y48N | Missense Mutation (SNP) | VAF 56/84 reads (67%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.994); catalogued as COSV51471394; called by muse, mutect2, varscan2
- ITGB2 | c.2062G>C p.E688Q (on ENST00000302347; = p.E664Q on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/31 reads (68%) | SIFT tolerated (0.13); PolyPhen benign (0.061); catalogued as COSV56608568; called by muse, mutect2, varscan2
- JMJD7-PLA2G4B | c.2017A>G p.K673E | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1225609165, COSV58017832; called by muse, mutect2, varscan2
- KCNA5 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1310058581, COSV52904426; called by muse, mutect2, varscan2
- KCNJ4 | c.584T>A p.V195E | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.633); catalogued as COSV57856437; called by muse, mutect2, varscan2
- KCNK2 | c.805T>A p.F269I (on ENST00000444842 / NM_001017425.3; = p.F254I on NM_014217.4) | Missense Mutation (SNP) | VAF 20/147 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.951); catalogued as COSV67203993; called by muse, mutect2, varscan2
- KCNN4 | c.1120A>G p.M374V | Missense Mutation (SNP) | VAF 46/77 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.191); catalogued as COSV53454848; called by muse, mutect2, varscan2
- KHDRBS2 | c.940T>A p.Y314N | Missense Mutation (SNP) | VAF 40/88 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55434868; called by muse, mutect2, varscan2
- KIAA1210 | c.1759T>A p.L587M | Missense Mutation (SNP) | VAF 38/40 reads (95%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.647); catalogued as COSV68176038; called by muse, mutect2, varscan2
- KIF26B | c.5012G>T p.R1671M | Missense Mutation (SNP) | VAF 37/69 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV63638413; called by muse, mutect2, varscan2
- KMT2B | c.3325C>T p.R1109* | Nonsense Mutation (SNP) | VAF 19/128 reads (15%) | catalogued as COSV55857935, COSV55869190; called by muse, mutect2, varscan2
- KRT37 | c.616G>A p.D206N | Missense Mutation (SNP) | VAF 21/44 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV56657239; called by muse, mutect2, varscan2
- LAMC3 | c.4404G>T p.E1468D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.033); catalogued as COSV100736140; called by muse, mutect2
- LRFN2 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 61/140 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100599020, COSV57824981; called by muse, mutect2, varscan2
- LRRC37A3 | c.1136A>G p.Q379R | Missense Mutation (SNP) | VAF 37/218 reads (17%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs765556062, COSV59760535; called by muse, mutect2, varscan2
- LYN | c.912G>T p.R304S | Missense Mutation (SNP) | VAF 58/161 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.36); catalogued as rs1183826897, COSV70205441; called by muse, mutect2, varscan2
- MACO1 | c.1159G>A p.E387K | Missense Mutation (SNP) | VAF 104/255 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65475445; called by muse, mutect2, varscan2
- MAOA | c.1338A>T p.E446D | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT tolerated (0.34); PolyPhen benign (0.158); catalogued as COSV58641626; called by muse, mutect2, varscan2
- MARF1 | c.1013C>A p.P338Q | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.867); catalogued as COSV60020765; called by muse, mutect2, varscan2
- MBTPS2 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 64/69 reads (93%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.622); catalogued as COSV63410950; called by muse, mutect2, varscan2
- MCOLN2 | c.1210A>T p.N404Y | Missense Mutation (SNP) | VAF 145/350 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52293957; called by muse, mutect2, varscan2
- MIB2 | c.1315A>T p.K439* | Nonsense Mutation (SNP) | VAF 39/71 reads (55%) | catalogued as COSV61755241; called by muse, mutect2, varscan2
- MIGA1 | c.1270C>T p.R424* | Nonsense Mutation (SNP) | VAF 34/94 reads (36%) | catalogued as rs1397414626, COSV66223037; called by muse, mutect2, varscan2
- MKX | c.741A>T p.Q247H | Missense Mutation (SNP) | VAF 61/114 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.26); catalogued as rs760341032, COSV65391732; called by muse, mutect2, varscan2
- MLH3 | c.3598A>G p.I1200V | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.946); catalogued as COSV53153078; called by muse, mutect2, varscan2
- MMP7 | c.380G>T p.R127L | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.042); catalogued as rs138303399, COSV52771550; called by muse, mutect2, varscan2
- MNX1 | c.691+2T>A p.X231_splice | Splice Site (SNP) | VAF 23/53 reads (43%) | catalogued as COSV53317806; called by muse, mutect2, varscan2
- MORC1 | c.2393G>T p.G798V | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV51716131; called by muse, mutect2, varscan2
- MRM2 | c.276G>C p.Q92H | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT tolerated (0.09); PolyPhen benign (0.023); catalogued as COSV54247715; called by muse, mutect2, varscan2
- MTR | c.2251A>T p.M751L | Missense Mutation (SNP) | VAF 24/94 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.05); catalogued as COSV63964111; called by muse, mutect2, varscan2
- MUC16 | c.15790T>G p.S5264A | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.329); catalogued as COSV67452538; called by muse, mutect2, varscan2
- MUC17 | c.1744G>A p.V582M | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT tolerated (0.1); PolyPhen benign (0.02); catalogued as COSV60282734; called by muse, mutect2, varscan2
- MYH11 | c.1373T>A p.L458Q | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55546144; called by muse, mutect2, varscan2
- NCSTN | c.1232T>G p.V411G | Missense Mutation (SNP) | VAF 36/132 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as COSV54186151; called by muse, mutect2, varscan2
- NEK11 | c.1159A>T p.S387C | Missense Mutation (SNP) | VAF 94/176 reads (53%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.518); catalogued as COSV63579483; called by muse, mutect2, varscan2
- NIPAL4 | c.1315G>A p.D439N | Missense Mutation (SNP) | VAF 40/60 reads (67%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV57424602, COSV99978906; called by muse, mutect2, varscan2
- NLRP2 | c.782T>A p.L261Q | Missense Mutation (SNP) | VAF 45/168 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54753127; called by muse, mutect2, varscan2
- NOTCH2 | c.5360G>A p.R1787Q | Missense Mutation (SNP) | VAF 7/112 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1317975644, COSV56685015, COSV99866574; called by muse, mutect2
- OLFM3 | c.1044C>A p.D348E (on ENST00000338858 / NM_001288821.1; = p.D328E on NM_058170.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 83/165 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV58796546; called by muse, mutect2, varscan2
- OR10G3 | c.427G>T p.A143S | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.29); PolyPhen benign (0.015); catalogued as rs376143433, COSV57809789; called by muse, mutect2, varscan2
- OR12D3 | c.734T>C p.M245T | Missense Mutation (SNP) | VAF 16/165 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV65826806; called by muse, mutect2, varscan2
- OR2L3 | c.428T>C p.M143T | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV63454705; called by muse, mutect2, varscan2
- OR5H14 | c.298C>A p.Q100K | Missense Mutation (SNP) | VAF 25/176 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.611); catalogued as COSV71193607; called by muse, mutect2, varscan2
- OR7C2 | c.83A>T p.H28L | Missense Mutation (SNP) | VAF 30/1168 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV99934696; called by muse, mutect2
- OR8D1 | c.341T>A p.L114H | Missense Mutation (SNP) | VAF 78/112 reads (70%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV63441832; called by muse, mutect2, varscan2
- OR8H1 | c.397G>A p.V133I | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs776470125, COSV57293424; called by muse, mutect2, varscan2
- OR8H2 | c.736T>G p.L246V | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.58); catalogued as COSV57943687; called by muse, mutect2, varscan2
- OSBPL7 | c.180G>T p.W60C | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV50107343, COSV50116079; called by muse, mutect2, varscan2
- OSCP1 | c.281A>T p.Q94L (on ENST00000356637 / NM_001330493.1; = p.Q84L on NM_145047.5) | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.216); catalogued as COSV52485209; called by muse, mutect2, varscan2
- P2RX6 | c.425A>T p.E142V | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.022); catalogued as COSV60382762, COSV60383921; called by muse, mutect2, varscan2
- P3H3 | c.656C>T p.A219V | Missense Mutation (SNP) | VAF 33/173 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.214); catalogued as rs868978668, COSV51831525; called by muse, mutect2, varscan2
- PCBP3 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.293); catalogued as COSV68406955; called by muse, mutect2, varscan2
- PCDHGB4 | c.2304T>A p.S768R | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV53914267; called by muse, mutect2, varscan2
- PHACTR3 | c.203T>A p.L68Q | Missense Mutation (SNP) | VAF 100/144 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV63025901; called by muse, mutect2, varscan2
- PHF14 | c.1040A>G p.H347R | Missense Mutation (SNP) | VAF 48/116 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV68854607; called by muse, mutect2, varscan2
- PLEKHG1 | c.1736A>G p.D579G | Missense Mutation (SNP) | VAF 49/58 reads (84%) | SIFT tolerated (0.14); PolyPhen benign (0.081); catalogued as COSV62045780; called by muse, mutect2, varscan2
- PLPPR5 | c.563G>T p.R188L | Missense Mutation (SNP) | VAF 38/87 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54170281, COSV99587182; called by muse, mutect2, varscan2
- PLSCR4 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV61607543; called by muse, mutect2, varscan2
- PNPLA3 | c.769A>T p.R257W | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.271); catalogued as COSV53377568; called by muse, mutect2
- POLN | c.470A>C p.K157T | Missense Mutation (SNP) | VAF 20/137 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as COSV67023932; called by muse, mutect2, varscan2
- PPM1E | c.1705T>A p.Y569N | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.775); catalogued as COSV57571727; called by muse, mutect2, varscan2
- PPP1R13B | c.1294T>G p.S432A | Missense Mutation (SNP) | VAF 29/51 reads (57%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV52449594; called by muse, mutect2, varscan2
- PREX1 | c.2093T>A p.L698Q | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as COSV64248997; called by muse, mutect2, varscan2
- PREX1 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 15/57 reads (26%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.977); catalogued as COSV64249006; called by muse, mutect2, varscan2
- PREX2 | c.4790G>T p.C1597F | Missense Mutation (SNP) | VAF 32/89 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55757484; called by muse, mutect2, varscan2
- PRR5-ARHGAP8 | c.1000T>G p.L334V (on ENST00000352766; = p.L255V on NM_181334.5) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.082); catalogued as COSV100424163, COSV61232045; called by muse, mutect2, varscan2
- PRTG | c.2324+2T>A p.X775_splice | Splice Site (SNP) | VAF 29/87 reads (33%) | catalogued as COSV66837165; called by muse, mutect2, varscan2
- PSMA7 | c.527A>G p.Y176C | Missense Mutation (SNP) | VAF 87/126 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs981402555, COSV53378771; called by muse, mutect2, varscan2
- PTGIR | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765751581, COSV52191657; called by muse, mutect2, varscan2
- PTPN13 | c.5060T>A p.V1687E (on ENST00000411767 / NM_080683.3; = p.V1668E on NM_006264.3) | Missense Mutation (SNP) | VAF 78/95 reads (82%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV57404071; called by muse, mutect2, varscan2
- PTPRM | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs917007136, COSV59848801; called by muse, mutect2, varscan2
- RASSF10 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV61754368; called by muse, mutect2, varscan2
- RB1 | c.1740A>C p.E580D | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV57299510; called by muse, mutect2, varscan2
- RBFOX1 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60950045; called by muse, mutect2, varscan2
- RBPJL | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 45/62 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370206478; called by muse, mutect2, varscan2
- RFX7 | c.1417G>A p.G473R (on ENST00000559447 / NM_001368074.1; = p.G570R on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.169); catalogued as COSV100428747, COSV57960917; called by muse, mutect2, varscan2
- RGS12 | c.3284A>G p.D1095G | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58749681; called by muse, mutect2, varscan2
- RGS16 | c.485T>A p.L162Q | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62375533; called by muse, mutect2, varscan2
- S1PR5 | c.1087T>A p.S363T | Missense Mutation (SNP) | VAF 14/17 reads (82%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61013459; called by muse, mutect2, varscan2
- SACS | c.6406A>T p.T2136S | Missense Mutation (SNP) | VAF 29/68 reads (43%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1566066009, COSV66536325; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SBF2 | c.3553T>C p.W1185R | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV56294081; called by muse, mutect2, varscan2
- SERPINB3 | c.443A>G p.N148S | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV52190239; called by muse, mutect2, varscan2
- SH3D19 | c.894T>A p.N298K | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV58789600; called by muse, mutect2, varscan2
- SHMT1 | c.469A>T p.K157* | Nonsense Mutation (SNP) | VAF 42/128 reads (33%) | catalogued as COSV57397928; called by muse, mutect2, varscan2
- SIPA1L3 | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377070862; called by muse, mutect2, varscan2
- SLC10A1 | c.109_111del p.F37del | In Frame Del (DEL) | VAF 38/82 reads (46%) | catalogued as rs1299867672; called by pindel, varscan2
- SLC12A1 | c.2602A>T p.N868Y | Missense Mutation (SNP) | VAF 85/146 reads (58%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as COSV66792777; called by muse, mutect2, varscan2
- SLC12A4 | c.1130A>T p.Q377L | Missense Mutation (SNP) | VAF 41/69 reads (59%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV57926429; called by muse, mutect2, varscan2
- SLC12A8 | c.97A>T p.M33L | Missense Mutation (SNP) | VAF 56/313 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV58863935, COSV58864163; called by muse, mutect2, varscan2
- SLC22A9 | c.1469T>C p.L490P | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54166273, COSV99654742; called by muse, mutect2, varscan2
- SLC22A9 | c.1617A>T p.R539S | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.104); catalogued as COSV54166282; called by muse, mutect2, varscan2
- SLC25A12 | c.1244A>T p.D415V | Missense Mutation (SNP) | VAF 32/157 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV55532029; called by muse, mutect2, varscan2
- SLC30A2 | c.868A>T p.S290C | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV65332376; called by muse, mutect2, varscan2
- SLC30A3 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs1165342398, COSV51984462; called by muse, mutect2, varscan2
- SLC6A15 | c.998A>T p.D333V | Missense Mutation (SNP) | VAF 242/328 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57021115; called by muse, mutect2, varscan2
- SMC6 | c.1682C>T p.P561L | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs745624947, COSV61172147; called by muse, mutect2
- SMCHD1 | c.3097A>T p.S1033C | Missense Mutation (SNP) | VAF 77/168 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55253128; called by muse, mutect2, varscan2
- SNAP91 | c.7G>T p.G3C | Missense Mutation (SNP) | VAF 39/40 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52117699; called by muse, mutect2, varscan2
- SPAST | c.1022T>A p.F341Y | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV59513235; called by muse, mutect2, varscan2
- SPEG | c.4532A>T p.K1511I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.671); catalogued as COSV56665151; called by muse, mutect2, varscan2
- SPINDOC | c.589C>T p.R197C | Missense Mutation (SNP) | VAF 19/30 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761075390, COSV53692134; called by muse, mutect2, varscan2
- SRD5A2 | c.342A>T p.R114S | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as COSV51870833; called by muse, mutect2, varscan2
- SRRM3 | c.924G>A p.W308* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | catalogued as COSV58386094; called by muse, mutect2, varscan2
- STK36 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 37/117 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.075); catalogued as COSV55324911; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2185C>G p.L729V | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV59127651; called by muse, mutect2, varscan2
- SWAP70 | c.790-2A>T p.X264_splice | Splice Site (SNP) | VAF 36/110 reads (33%) | catalogued as COSV59662806; called by muse, mutect2, varscan2
- TASP1 | c.551C>A p.P184H | Missense Mutation (SNP) | VAF 28/41 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV61811952; called by muse, mutect2, varscan2
- TCF21 | c.365G>A p.R122K | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV52818032; called by muse, mutect2, varscan2
- TERF1 | c.476G>C p.G159A | Missense Mutation (SNP) | VAF 129/340 reads (38%) | SIFT tolerated (0.91); PolyPhen benign (0.001); catalogued as COSV52577024; called by muse, mutect2, varscan2
- TEX15 | c.1163T>C p.I388T (on ENST00000256246; = p.I771T on NM_001350162.2) | Missense Mutation (SNP) | VAF 48/57 reads (84%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV56343237; called by muse, mutect2, varscan2
- TNXB | c.11044A>T p.I3682F (on ENST00000647633; = p.I3435F on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs1307962610, COSV64475347; called by muse, mutect2, varscan2
- TP53BP1 | c.5587C>A p.Q1863K | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV53018118; called by muse, mutect2, varscan2
- TPRX1 | c.953C>G p.P318R | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.721); catalogued as rs767710487, COSV59115240; called by mutect2, varscan2
- TPRX1 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 22/216 reads (10%) | SIFT tolerated (0.53); PolyPhen benign (0.386); catalogued as rs202132729; called by muse, mutect2
- TTC14 | c.646C>A p.L216I | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.09); catalogued as COSV56009948; called by muse, mutect2, varscan2
- TTN | c.17356G>A p.E5786K (on ENST00000591111; = p.E4859K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | PolyPhen probably damaging (0.994); catalogued as COSV59935706; called by muse, mutect2, varscan2
- TULP3 | c.1052A>T p.Q351L | Missense Mutation (SNP) | VAF 89/120 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV68117492; called by muse, mutect2, varscan2
- UBE2Q1 | c.452G>A p.R151K | Missense Mutation (SNP) | VAF 20/94 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.005); catalogued as COSV52724235; called by muse, mutect2, varscan2
- UCHL1 | c.562A>T p.S188C | Missense Mutation (SNP) | VAF 50/91 reads (55%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV52651223; called by muse, mutect2, varscan2
- URM1 | c.19G>C p.V7L | Missense Mutation (SNP) | VAF 28/35 reads (80%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV65717018; called by muse, mutect2, varscan2
- USP48 | c.364A>T p.S122C | Missense Mutation (SNP) | VAF 139/284 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); catalogued as COSV57607978; called by muse, mutect2, varscan2
- UTP20 | c.1647G>T p.M549I | Missense Mutation (SNP) | VAF 170/188 reads (90%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as COSV55373811; called by muse, mutect2, varscan2
- VLDLR | c.400T>A p.C134S | Missense Mutation (SNP) | VAF 47/56 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66073397; called by muse, mutect2, varscan2
- VPS45 | c.1097C>T p.A366V | Missense Mutation (SNP) | VAF 114/168 reads (68%) | SIFT tolerated (0.31); PolyPhen benign (0.099); catalogued as rs782085785, COSV64887183; called by muse, mutect2, varscan2
- VSTM4 | c.674G>T p.G225V | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); catalogued as rs764695395, COSV60525022; called by muse, mutect2, varscan2
- WASF3 | c.153A>G p.I51M | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV58963543; called by muse, mutect2
- ZBED8 | c.968G>C p.S323T | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV68824432; called by muse, mutect2, varscan2
- ZC3H6 | c.421A>T p.S141C | Missense Mutation (SNP) | VAF 78/238 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59666571; called by muse, mutect2, varscan2
- ZFAND1 | c.683A>G p.D228G | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.493); catalogued as COSV55107011; called by muse, mutect2, varscan2
- ZFP64 | c.323A>T p.Q108L | Missense Mutation (SNP) | VAF 62/89 reads (70%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV53797208; called by muse, mutect2, varscan2
- ZNF16 | c.395A>T p.Q132L | Missense Mutation (SNP) | VAF 45/87 reads (52%) | SIFT tolerated (0.07); PolyPhen benign (0.025); catalogued as COSV52763002; called by muse, mutect2, varscan2
- ZNF256 | c.692G>C p.G231A | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as COSV56596555, COSV56597557; called by muse, mutect2, varscan2
- ZNF454 | c.1124A>T p.Q375L | Missense Mutation (SNP) | VAF 32/95 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as COSV60767326; called by muse, mutect2, varscan2
- ZNF486 | c.1264A>G p.T422A | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.758); catalogued as COSV58717880; called by muse, mutect2, varscan2
- ZNF808 | c.674A>T p.H225L | Missense Mutation (SNP) | VAF 94/147 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.472); catalogued as COSV63119032; called by muse, mutect2, varscan2
- DHX16 | c.3097dup p.I1033Nfs*34 | Frame Shift Ins (INS) | VAF 72/139 reads (52%) | called by mutect2, varscan2
- PRR12 | c.1680_1682del p.S561del (on ENST00000615927; = p.S1382del on NM_020719.3) | In Frame Del (DEL) | VAF 20/118 reads (17%) | called by pindel, varscan2
- SETBP1 | c.556del p.Q186Rfs*21 | Frame Shift Del (DEL) | VAF 22/51 reads (43%) | called by mutect2, pindel, varscan2
- TAS2R9 | c.584dup p.I196Dfs*12 | Frame Shift Ins (INS) | VAF 23/164 reads (14%) | called by mutect2, pindel, varscan2
- TMX2 | c.297_308del p.A100_I103del | In Frame Del (DEL) | VAF 34/89 reads (38%) | called by mutect2, pindel, varscan2
- TP53 | c.743_750del p.R248Hfs*13 | Frame Shift Del (DEL) | VAF 26/31 reads (84%) | called by mutect2, pindel, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 21/75 reads (28%) | called by mutect2, pindel, varscan2
- ABCA5 | c.2028T>A p.A676= | Silent (SNP) | VAF 19/98 reads (19%) | catalogued as COSV67016069; called by muse, mutect2, varscan2
- ACTN4 | c.1032G>A p.P344= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as rs753535029, COSV53143849; called by muse, mutect2
- ADAMTS20 | c.2886T>C p.H962= | Silent (SNP) | VAF 90/135 reads (67%) | catalogued as COSV67128830; called by muse, mutect2, varscan2
- ADGRA1 | c.1443C>T p.V481= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as COSV66925120; called by muse, mutect2, varscan2
- ADGRL3 | c.3276T>C p.F1092= (on ENST00000506720 / NM_001322402.2; = p.F1024= on NM_015236.6) | Silent (SNP) | VAF 46/59 reads (78%) | catalogued as COSV72229897; called by muse, mutect2, varscan2
- ADGRV1 | c.12297G>A p.Q4099= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as COSV67980410; called by muse, mutect2, varscan2
- AHCTF1 | c.5661A>T p.P1887= (on ENST00000366508; = p.P1861= on NM_015446.5) | Silent (SNP) | VAF 145/231 reads (63%) | catalogued as COSV58247074; called by muse, mutect2, varscan2
- AIM2 | c.222T>C p.Y74= | Silent (SNP) | VAF 77/213 reads (36%) | catalogued as rs145394745; called by muse, mutect2, varscan2
- ATF6 | c.1614A>T p.S538= | Silent (SNP) | VAF 63/215 reads (29%) | catalogued as COSV63406429; called by muse, mutect2, varscan2
- BCOR | c.2484A>T p.A828= | Silent (SNP) | VAF 37/42 reads (88%) | catalogued as COSV60702561; called by muse, mutect2, varscan2
- CDH20 | c.237T>C p.Y79= | Silent (SNP) | VAF 45/105 reads (43%) | catalogued as rs777015854, COSV53006236; called by muse, mutect2, varscan2
- CELSR2 | c.3735G>A p.S1245= | Silent (SNP) | VAF 17/65 reads (26%) | catalogued as rs1178141209, COSV54768390; called by muse, mutect2, varscan2
- COL12A1 | c.2187A>T p.L729= | Silent (SNP) | VAF 33/36 reads (92%) | catalogued as COSV59391605; called by muse, mutect2, varscan2
- COL3A1 | c.1809C>A p.G603= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as COSV58583947; called by muse, mutect2
- DHTKD1 | c.447G>T p.R149= | Silent (SNP) | VAF 60/125 reads (48%) | catalogued as rs757610245, COSV53802281; called by muse, mutect2, varscan2
- DIS3L2 | c.312A>G p.R104= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as COSV56050189; called by muse, mutect2, varscan2
- FLT1 | c.1224C>T p.S408= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs898618342, COSV56721122; called by muse, mutect2, varscan2
- GUCY1A2 | c.1137G>A p.L379= | Silent (SNP) | VAF 34/118 reads (29%) | catalogued as COSV56480710, COSV56506554; called by muse, mutect2, varscan2
- KRT35 | c.312G>C p.L104= | Silent (SNP) | VAF 53/97 reads (55%) | catalogued as COSV55842540, COSV99877919; called by muse, mutect2, varscan2
- KRT40 | c.324C>A p.R108= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as COSV66696085; called by muse, mutect2, varscan2
- LARP4 | c.1896A>T p.S632= | Silent (SNP) | VAF 43/164 reads (26%) | catalogued as COSV53320877; called by muse, mutect2, varscan2
- MAGEC1 | c.1386C>A p.S462= | Silent (SNP) | VAF 12/116 reads (10%) | catalogued as COSV53569648, COSV99596460; called by muse, mutect2, varscan2
- MRPS33 | c.96A>G p.K32= | Silent (SNP) | VAF 54/146 reads (37%) | catalogued as COSV61341156; called by muse, mutect2, varscan2
- MSR1 | c.60T>A p.S20= | Silent (SNP) | VAF 33/38 reads (87%) | catalogued as COSV50508115; called by muse, mutect2, varscan2
- MYT1L | c.1095G>A p.E365= | Silent (SNP) | VAF 16/67 reads (24%) | catalogued as COSV67712743; called by muse, mutect2, varscan2
- NOL4L | c.348G>A p.L116= | Silent (SNP) | VAF 11/45 reads (24%) | catalogued as COSV62889145; called by muse, mutect2, varscan2
- NTNG2 | c.1290C>A p.R430= | Silent (SNP) | VAF 21/22 reads (95%) | catalogued as COSV62365230; called by muse, mutect2, varscan2
- OPHN1 | c.1737T>A p.P579= | Silent (SNP) | VAF 85/92 reads (92%) | catalogued as COSV62780946; called by muse, mutect2, varscan2
- PHF10 | c.903A>T p.S301= | Silent (SNP) | VAF 141/164 reads (86%) | catalogued as COSV59321346; called by muse, mutect2, varscan2
- PIAS2 | c.1422A>C p.I474= | Silent (SNP) | VAF 31/67 reads (46%) | catalogued as COSV61342481; called by muse, mutect2, varscan2
- POLR2B | c.1332A>T p.L444= | Silent (SNP) | VAF 104/435 reads (24%) | catalogued as COSV58899124; called by muse, mutect2, varscan2
- PRAF2 | c.111C>A p.V37= | Silent (SNP) | VAF 31/38 reads (82%) | catalogued as COSV59875585; called by muse, mutect2, varscan2
- RBM28 | c.495A>C p.L165= | Silent (SNP) | VAF 40/96 reads (42%) | catalogued as COSV56161987; called by muse, mutect2, varscan2
- RDM1 | c.246G>T p.R82= | Silent (SNP) | VAF 29/150 reads (19%) | called by muse, mutect2, varscan2
- RGS20 | c.480C>T p.D160= | Silent (SNP) | VAF 19/90 reads (21%) | catalogued as COSV52014803; called by muse, mutect2, varscan2
- RLBP1 | c.714C>A p.I238= | Silent (SNP) | VAF 83/199 reads (42%) | catalogued as COSV51527466; called by muse, mutect2, varscan2
- RNASE1 | c.129A>T p.S43= | Silent (SNP) | VAF 8/41 reads (20%) | catalogued as COSV61753889; called by muse, mutect2, varscan2
- RSRP1 | c.568C>T p.L190= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as rs147790749; called by muse, mutect2, varscan2
- RTBDN | c.585A>T p.G195= (on ENST00000393233 / NM_001270444.1; = p.G227= on NM_031429.2) | Silent (SNP) | VAF 85/99 reads (86%) | catalogued as COSV59806005; called by muse, mutect2, varscan2
- SAMD1 | c.126G>A p.L42= | Silent (SNP) | VAF 8/172 reads (5%) | catalogued as COSV54115925; called by muse, mutect2
- STAT6 | c.1059G>C p.G353= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs1441640359, COSV55669649, COSV55671652; called by muse, mutect2, varscan2
- SYNE2 | c.9843C>G p.P3281= | Silent (SNP) | VAF 56/167 reads (34%) | catalogued as COSV59942793; called by muse, mutect2, varscan2
- TIMD4 | c.351T>A p.P117= | Silent (SNP) | VAF 41/63 reads (65%) | catalogued as COSV50854284; called by muse, mutect2, varscan2
- TMEM259 | c.405G>C p.G135= | Silent (SNP) | VAF 32/95 reads (34%) | catalogued as COSV52259002; called by muse, mutect2, varscan2
- TP53INP1 | c.246C>A p.S82= | Silent (SNP) | VAF 22/154 reads (14%) | catalogued as COSV61330916; called by muse, varscan2
- TREML1 | c.372C>T p.P124= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as COSV58294010; called by muse, mutect2, varscan2
- TTLL2 | c.1311C>A p.I437= | Silent (SNP) | VAF 54/56 reads (96%) | catalogued as rs201555411, COSV53442917, COSV53442993; called by muse, mutect2, varscan2
- TTN | c.91866T>A p.T30622= (on ENST00000591111; = p.T23198= on NM_003319.4) | Silent (SNP) | VAF 40/70 reads (57%) | catalogued as COSV59935676; called by muse, mutect2, varscan2
- USP42 | c.2007G>A p.P669= | Silent (SNP) | VAF 27/45 reads (60%) | catalogued as rs750773438, COSV60358457; called by muse, mutect2, varscan2
- VSIG10 | c.225A>T p.P75= | Silent (SNP) | VAF 123/130 reads (95%) | catalogued as COSV63652443; called by muse, mutect2, varscan2
- YBX1 | c.735C>T p.F245= | Silent (SNP) | VAF 53/168 reads (32%) | catalogued as rs1344500059, COSV58437649; called by muse, mutect2, varscan2
- BIRC8 | n.1258T>A | RNA (SNP) | VAF 118/186 reads (63%) | catalogued as COSV70346565; called by muse, mutect2, varscan2
- TTN | c.10361-5005T>G | Intron (SNP) | VAF 25/75 reads (33%) | catalogued as COSV59935715; called by muse, mutect2, varscan2
